Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A49W, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A49W-01A (Primary Tumor).

[page 1 of 6]
Tel:

Fax:

Clinical Case Report

(For Collection of Cancerous Tissue)

1CD-0-3

Carcinoma, squamous cell, NOS 8070/3
Site: esophagus, middle third C15.4

lw
10/5/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	VIETNAMESE	
☒ Male ☐ Female	61 kg	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
			13/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Trouble Swallowing
Symptoms: Fever ; weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses		# of Pregnancies
	Date of Last Menses		# of Live Births
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____			☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		1 p/day	2 (yrs)	1 yr ago (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO			(yrs)	3 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers: _____						

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy ✓	Carcinoma	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes		Location of Suspected Distant Metastasis
Clinical Staging		Date of Diagnosis
T ₃ N ₁ M ₀ Stage: III		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of the upper part of the oesophagus			
Primary Tumor			
Organ	Detailed Location	Size	
oesophagus tumor	oesophagus middle	7 x 2.5 x 1.5 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T ₃	N ₁	M ₀	Stage: IV

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by: ____

____ Date:

Time: ____

Preserved by: ____

____ Date:

Time: ____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
13 min		14 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
oesophagus Tumor	7 x 2.5 x 1.5 cm	oesophagus middle	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃ N ₁ M ₀ Stage: III			
Notes: Nade (M ₁ , M ₂)			

[page 5 of 6]
Microscopic Description

Histological Pattern															
Cell Distribution			+	-	Structural Pattern			+	-						
Diffuse					Streaming										
Mosaic					Storiform										
Necrosis					Fibrosis										
Lymphocytic Infiltration					Palisading										
Vascular Invasion					Cystic Degeneration										
Clusterized					Bleeding										
Alveolar Formation					Myxoid Change										
Indian File					Psammoma/Calcification										
Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell				Glandular cell				Round Cell				Large Cell			
Spindle Cell				Cell Stratification				Fibroblast				Small Cell			
Keratin				Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl				Gland formation				Myoblast				Plasma Cell			
Cellular Differentiation: ☒ Well ☐ Moderate ☐ Poor															
Nuclear Appearance															
Nuclear Atypia:						0	I	II	III						
Aniso Nucleosis															
Hyperchromatism															
Nucleolar Prominent															
Multinucleated Giant Cell															
Mitotic Activity															
Nuclear Grade:															

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Squamous cell carcinoma of the oropharynx
(well differentiated) **Grade:** 1

Comments: M_1, M_2 (positive)

Pathologist

Date _____

[page 6 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			X	Streaming			
Mosaic		X	X	Storiform			
Necrosis		X	X	Fibrosis			
Lymphocytic Infiltration		X	X	Palisading			
Vascular Invasion			X	Cystic Degeneration			
Clusterized		X		Bleeding			
Alveolar Formation			X	Myxoid Change			
Indian File			X	Psammoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Otherwise Specified:

D1 50%, D2 65%, D3 40%, D4 50%

2. Cellular Differentiation:

Well	Moderately	Poor
		X

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				X
Hyperchromatism			X	
Nucleolar Prominent				X
Multinucleated Giant Cell			X	
Mitotic Activity				X
Nuclear Grade				
				X

Histological Diagnosis: *Squamous cell carcinoma G3*

Comments: *M1, - M2: carcinoma metastasized to LN.*

Date

TO REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Pathologist Initials:	KVA	

Source: NCI Genomic Data Commons file 75818aa2-09b7-44de-8f83-da77e6ae0eb0 (TCGA-LN-A49W.38309E84-2CFD-4D1B-8AF4-D8F711679B26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).